Somatic mutation profile of tumor specimen 0DDLPM from CCDI case PBBMJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.5 years (3,105 days).
Specimen 0DDLPM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4326f982-e847-418d-9599-239a2a576783.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDLPE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00ced7c8-2def-45db-bbc2-f0fcd774062c

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PROSER3 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 131/726 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.756); catalogued as rs771205977, COSV56554592; called by muse, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 46/1374 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KIF20B | c.4433A>G p.N1478S (on ENST00000371728 / NM_001284259.2; = p.N1438S on NM_016195.4) | Missense Mutation (SNP) | VAF 56/1152 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- SPATS2L | c.1051T>C p.C351R | Missense Mutation (SNP) | VAF 79/908 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF316 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 46/1127 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- PCDH7 | c.933C>T p.S311= | Silent (SNP) | VAF 151/800 reads (19%) | catalogued as rs376019479; called by muse, mutect2, varscan2
- STAU1 | c.861G>A p.P287= (on ENST00000371856 / NM_001319135.1; = p.P206= on NM_004602.3) | Silent (SNP) | VAF 106/1474 reads (7%) | catalogued as rs146422110; called by muse, mutect2
- DDX60 | c.4270-45T>A | Intron (SNP) | VAF 11/166 reads (7%) | called by muse, mutect2
